Somatic mutation profile of tumor specimen TCGA-WE-AAA4-06A (aliquot TCGA-WE-AAA4-06A-12D-A38G-08) from TCGA case TCGA-WE-AAA4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.0 years (20,802 days).
Specimen TCGA-WE-AAA4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b318a906-c707-40d4-9fa6-dc5e0db49deb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-AAA4-10A (Blood Derived Normal), aliquot TCGA-WE-AAA4-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8380506b-2e01-46f9-9bc3-940061a98473

The open-access MAF lists 265 somatic variants for this specimen: 183 protein-altering or splice-affecting, 75 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 75, Nonsense Mutation 12, Splice Site 4, Intron 3, RNA 3, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2977T>C p.Y993H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.75); catalogued as COSV100750489; called by muse, mutect2, varscan2
- ACSL6 | c.1925G>A p.G642E (on ENST00000379240; = p.G667E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57302472; called by muse, mutect2
- ADAM29 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV63665486; called by muse, mutect2, varscan2
- ADAMTS6 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.033); catalogued as COSV101124626; called by muse, mutect2, varscan2
- ADGRG4 | c.5849G>A p.G1950E | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99794246; called by muse, mutect2, varscan2
- AHNAK2 | c.8960C>T p.S2987L | Missense Mutation (SNP) | VAF 110/630 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs948918668, COSV60912760; called by muse, mutect2, varscan2
- AIMP1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as rs373122636; called by muse, mutect2, varscan2
- AIRE | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs1239318349, COSV99380954; called by muse, mutect2, varscan2
- ALOX15 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as COSV53396590; called by muse, mutect2
- ALOXE3 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100559596; called by muse, mutect2, varscan2
- AQR | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1328833618, COSV50030198; called by muse, mutect2, varscan2
- ARHGAP10 | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60606700; called by muse, mutect2, varscan2
- ARMCX2 | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100168011; called by muse, mutect2, varscan2
- ARMCX2 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100168012; called by muse, mutect2, varscan2
- ARSH | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781634606, COSV101139735, COSV66963762; called by muse, mutect2, varscan2
- AXL | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as rs751738506, COSV56566509; called by muse, mutect2, varscan2
- BCAS3 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV101175025; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3373C>T p.P1125S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1225959583, COSV100863580; called by muse, mutect2, varscan2
- BRINP2 | c.2066G>A p.S689N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100837812, COSV100838536; called by muse, mutect2, varscan2
- CCAR1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99770545; called by muse, mutect2, varscan2
- CCDC33 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100350482; called by muse, mutect2
- CD1E | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63772397; called by muse, mutect2, varscan2
- CD2 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV65644712; called by muse, mutect2
- CD22 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs763054158, COSV50050193, COSV50058335; called by muse, mutect2, varscan2
- CD22 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50064334, COSV99322788; called by muse, mutect2
- CENPI | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 41/221 reads (19%) | catalogued as COSV99514982; called by muse, mutect2, varscan2
- CEP44 | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99639153; called by muse, mutect2, varscan2
- CHRM3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487020414, COSV55093240, COSV55095451; called by muse, mutect2, varscan2
- CKMT2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs748332374, COSV99562240; called by muse, mutect2, varscan2
- CLSTN3 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs780769952, COSV99866452; called by muse, mutect2, varscan2
- CLTA | c.698G>A p.R233H (on ENST00000242285 / NM_007096.4; = p.R203H on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376238055; called by muse, mutect2, varscan2
- CMYA5 | c.10361G>A p.G3454E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV71409015; called by muse, mutect2
- CNTNAP4 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56690760; called by muse, mutect2
- COL2A1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV100475338; called by muse, mutect2, varscan2
- CPA4 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99743728; called by muse, mutect2
- CPA4 | c.68+1G>A p.X23_splice | Splice Site (SNP) | VAF 10/98 reads (10%) | catalogued as rs1562926594, COSV55979179; called by muse, mutect2
- CRKL | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100574026; called by muse, mutect2, varscan2
- CTNNA2 | c.1703A>T p.E568V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1362807808, COSV100559385; called by muse, mutect2, varscan2
- CTTNBP2 | c.1654C>T p.L552F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352914; called by muse, mutect2, varscan2
- CYFIP2 | c.2536G>A p.D846N (on ENST00000616178 / NM_001291722.2; = p.D821N on NM_014376.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as rs776958013, COSV56636556; called by muse, mutect2
- CYP2C18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53669788, COSV99608889; called by muse, mutect2
- CYP4X1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV64151019; called by muse, mutect2, varscan2
- DCAF11 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771012127, COSV58110956; called by muse, mutect2, varscan2
- DCDC1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100662659; called by muse, mutect2
- DDIT4L | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1305158917, COSV56767406, COSV99913794; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- DDX39A | c.541A>G p.N181D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99660114; called by muse, mutect2, varscan2
- DHRS4L2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100632259; called by muse, mutect2, varscan2
- DLEC1 | c.2186G>A p.S729N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1449397155, COSV100341383; called by muse, mutect2, varscan2
- DLGAP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99332113; called by muse, mutect2, varscan2
- DNAH8 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.085); catalogued as rs769997917, COSV100543114; called by muse, mutect2, varscan2
- DNAJC5B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV52536452; called by muse, mutect2, varscan2
- DOCK11 | c.2497C>T p.H833Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.105); catalogued as rs1319550798, COSV99352767; called by muse, mutect2, varscan2
- DPP3 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855413; called by muse, mutect2, varscan2
- DSP | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs1377309647, COSV60939691; called by muse, mutect2, varscan2
- EGFR | c.1390T>C p.S464P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV99286479; called by mutect2, varscan2
- EMILIN2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as COSV99598087; called by muse, mutect2, varscan2
- EPHA8 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs201777623, COSV99384139; called by muse, mutect2, varscan2
- ERICH3 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV100443174; called by muse, mutect2, varscan2
- ERN2 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as COSV55622051, COSV99890494; called by muse, mutect2
- EVC | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53830136; called by muse, mutect2, varscan2
- FGA | c.2574G>A p.M858I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV57396117; called by muse, mutect2, varscan2
- FLG2 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV101165578; called by muse, mutect2
- FLG2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV101165579; called by muse, mutect2, varscan2
- GABRB2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99195628; called by muse, mutect2, varscan2
- GABRB2 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as rs1365352964; called by muse, mutect2, varscan2
- GRID2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56170467, COSV99936908; called by muse, mutect2, varscan2
- GRIK1 | c.551T>A p.I184N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100515780; called by muse, mutect2, varscan2
- GRPR | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100977621; called by muse, mutect2, varscan2
- H2AC1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1418751341, COSV51237093, COSV99219604; called by muse, mutect2, varscan2
- HEPHL1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs374346546; called by muse, mutect2, varscan2
- IL13RA1 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100861687; called by muse, mutect2, varscan2
- IRF8 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV51899715; called by muse, mutect2
- ITPR2 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV101189797; called by muse, mutect2, varscan2
- JADE3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs144788692, COSV99509494; called by muse, mutect2, varscan2
- KDM2B | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997143, COSV65640684; called by muse, mutect2, varscan2
- KDR | c.429C>G p.N143K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV55777629, COSV99816632; called by muse, mutect2, varscan2
- KIAA1549L | c.3172T>C p.Y1058H (on ENST00000321505; = p.Y1355H on NM_012194.3) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99682554; called by muse, mutect2, varscan2
- KIF3B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100996308; called by muse, mutect2, varscan2
- KLF5 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs1330087707, COSV100890482; called by muse, mutect2, varscan2
- LGR6 | c.1652C>T p.P551L (on ENST00000367278 / NM_001017403.1; = p.P499L on NM_021636.3) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756414761, COSV99705933; called by muse, mutect2, varscan2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, mutect2, varscan2
- MAGEA1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV100756606; called by muse, mutect2, varscan2
- MAGEB6 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100983648; called by muse, mutect2, varscan2
- MAGEE1 | c.1847G>A p.R616K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.508); catalogued as COSV100819242; called by muse, mutect2, varscan2
- ME1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV63839392; called by muse, mutect2
- MED26 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1377764948, COSV99659771; called by muse, mutect2, varscan2
- MEP1B | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99328620; called by muse, mutect2, varscan2
- MFHAS1 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs1390373255, COSV99359129; called by muse, mutect2, varscan2
- MGAM | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868995180, COSV72074117; called by muse, mutect2, varscan2
- MROH2B | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV101270455; called by muse, mutect2
- MUC16 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs752541287, COSV101197949; called by muse, mutect2, varscan2
- MYBPC1 | c.1345G>A p.E449K (on ENST00000550270 / NM_206820.2; = p.E474K on NM_002465.4) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV62252081, COSV62256429; called by muse, mutect2, varscan2
- MYH8 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101238123; called by muse, mutect2, varscan2
- MYLK | c.2391G>A p.K797= | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100658460; called by muse, mutect2, varscan2
- NBEA | c.6614G>A p.G2205E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV59805566; called by muse, mutect2
- NBPF3 | c.1475T>A p.L492* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100558356; called by muse, mutect2, varscan2
- NEU3 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV53636232; called by muse, mutect2, varscan2
- NLRP9 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60466023; called by muse, mutect2, varscan2
- NOS1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV100499967, COSV100500722; called by muse, mutect2
- NT5C3A | c.308-1G>A p.X103_splice (on ENST00000610140 / NM_001374335.1; = p.X69_splice on NM_016489.13) | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54236749, COSV99640883; called by muse, mutect2
- OLFM3 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs760547171, COSV100919443; called by muse, mutect2, varscan2
- OR10AG1 | c.657G>C p.L219F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100399973; called by muse, mutect2, varscan2
- OR10H5 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100454624; called by muse, mutect2, varscan2
- OR14A16 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV100713684; called by muse, mutect2, varscan2
- OR2L8 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV100594017; called by muse, mutect2, varscan2
- OR2T6 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1480622972, COSV100861474; called by muse, mutect2, varscan2
- OR52J3 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757298367, COSV66746970; called by muse, mutect2, varscan2
- OR5K1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100220859; called by muse, mutect2, varscan2
- OR6V1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV101389178; called by muse, mutect2, varscan2
- PADI1 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.315); catalogued as rs748536566, COSV100968945, COSV100968971; called by muse, mutect2, varscan2
- PCCA | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100886485; called by muse, mutect2, varscan2
- PCDHA5 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs781965258, COSV100972072; called by muse, mutect2, varscan2
- PCDHB1 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1416593174, COSV60631514; called by muse, mutect2, varscan2
- PDCD1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57690889; called by muse, mutect2, varscan2
- PDGFA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627255; called by muse, mutect2, varscan2
- PENK | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100152135; called by muse, mutect2, varscan2
- PLCB4 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs886056980, COSV99594176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB3 | c.5000C>A p.P1667Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100737069; called by muse, mutect2
- PPP4R4 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100428228; called by muse, mutect2
- PRAMEF18 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 12/190 reads (6%) | catalogued as rs777204445; called by muse, mutect2
- PTK2 | c.2299C>T p.L767F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1038528814, COSV61783726; called by muse, mutect2, varscan2
- PTPN5 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1384350284, COSV100659604; called by muse, mutect2, varscan2
- PXDN | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53231925, COSV99412151; called by muse, mutect2, varscan2
- PYGB | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs202165304, COSV99404827; called by mutect2, varscan2
- RAPGEF2 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); catalogued as rs772043174, COSV52431374, COSV52434824; called by muse, mutect2
- RCN3 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.39); catalogued as rs1166272143, COSV99571132; called by muse, mutect2, varscan2
- RFPL2 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs562830791; called by muse, mutect2, varscan2
- RIDA | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54704656; called by muse, mutect2, varscan2
- RNF17 | c.3975+1G>A p.X1325_splice | Splice Site (SNP) | VAF 17/97 reads (18%) | catalogued as COSV55044455; called by muse, mutect2, varscan2
- ROR1 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100934859; called by muse, mutect2, varscan2
- RPL8 | c.179A>C p.K60T | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV52798854; called by muse, mutect2
- RPN1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749479360, COSV99956849; called by muse, mutect2, varscan2
- RPS6KA6 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV53122490, COSV99424592; called by muse, mutect2
- SATL1 | c.1214G>A p.G405D (on ENST00000395409; = p.G592D on NM_001012980.2) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.181); catalogued as rs1254612901, COSV100260661; called by muse, mutect2, varscan2
- SBF1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100817390; called by muse, mutect2, varscan2
- SCN3A | c.5392G>A p.E1798K | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51807759; called by muse, mutect2, varscan2
- SCN7A | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV101313068; called by muse, mutect2
- SCYL1 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1455034490, COSV99533703; called by muse, mutect2
- SEMA4A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV100740418; called by muse, mutect2, varscan2
- SERPINA7 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100568197; called by muse, mutect2, varscan2
- SEZ6L | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866486034, COSV99961259; called by muse, mutect2, varscan2
- SHOC1 | c.3273+2T>C p.X1091_splice | Splice Site (SNP) | VAF 20/118 reads (17%) | catalogued as rs1315099802, COSV100597223; called by muse, mutect2, varscan2
- SIGLEC10 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100218426; called by muse, mutect2, varscan2
- SIM2 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99292838; called by muse, mutect2, varscan2
- SLC38A4 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772180082, COSV56965176; called by muse, mutect2, varscan2
- SLC39A10 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs866722985, COSV100660463; called by muse, mutect2, varscan2
- SLC6A14 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100903058; called by muse, mutect2, varscan2
- SPATA21 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs762570991, COSV100130552, COSV59186469; called by muse, mutect2, varscan2
- SPHKAP | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as COSV100763650, COSV60871125; called by muse, mutect2, varscan2
- SRD5A3 | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99947976; called by muse, mutect2, varscan2
- SSTR1 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV99942674; called by muse, mutect2, varscan2
- ST8SIA2 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | PolyPhen probably damaging (0.99); catalogued as rs1370355309, COSV51570535; called by muse, mutect2
- STEAP2 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs142681801; called by mutect2, varscan2
- SUN5 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479639792, COSV100644767; called by muse, mutect2, varscan2
- TAF1L | c.2449A>T p.R817W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99644053; called by muse, mutect2, varscan2
- TANGO6 | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99935602; called by muse, mutect2
- TCF4 | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100609281; called by muse, mutect2, varscan2
- THRAP3 | c.1783C>T p.R595* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV63568365; called by muse, mutect2
- TLL1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99285961; called by muse, mutect2, varscan2
- TM9SF4 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV99453851; called by muse, mutect2, varscan2
- TMEM135 | c.138C>A p.Y46* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100449298; called by muse, mutect2, varscan2
- TMPRSS13 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV70627317; called by muse, mutect2
- TNR | c.4039C>T p.L1347F | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99687316; called by muse, mutect2, varscan2
- TRERF1 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1561875595, COSV61677446; called by muse, mutect2, varscan2
- TRGC2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746275832; called by muse, mutect2, varscan2
- TRIM56 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV100046888; called by muse, mutect2, varscan2
- TSHZ2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61591164; called by muse, mutect2, varscan2
- TTN | c.6831A>C p.E2277D (on ENST00000591111; = p.E2231D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | PolyPhen probably damaging (0.99); catalogued as COSV100592610; called by muse, mutect2, varscan2
- UBTD2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV101196301; called by muse, mutect2
- UGT2B15 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767748124, COSV57733623; called by muse, mutect2
- VCAM1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99658153; called by muse, mutect2, varscan2
- VRK3 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100371248; called by muse, mutect2, varscan2
- WDR17 | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99706646; called by muse, mutect2, varscan2
- WDR44 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs866586082, COSV54164892; called by muse, mutect2, varscan2
- WNT8A | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100843005; called by muse, mutect2
- ZCCHC13 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100272448; called by muse, mutect2
- ZNF544 | c.1094G>C p.C365S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99516746; called by muse, mutect2, varscan2
- ZNF711 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.368); catalogued as COSV99340611; called by muse, mutect2, varscan2
- ZNF804A | c.1860G>A p.M620I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100166263, COSV56438048; called by muse, mutect2, varscan2
- PRAMEF19 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 24/492 reads (5%) | called by muse, mutect2
- ABCA3 | c.3837C>T p.V1279= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs377568144; called by muse, mutect2
- AC136428.1 | c.88T>C p.L30= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV71169132; called by muse, mutect2, varscan2
- ACER1 | c.345G>A p.G115= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs911325509, COSV56834739; called by muse, mutect2, varscan2
- ADCY1 | c.1086G>A p.Q362= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99811194; called by muse, mutect2, varscan2
- AKAP6 | c.2790C>A p.L930= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99797986, COSV99803177; called by muse, mutect2, varscan2
- AOC1 | c.885C>T p.I295= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1287632038, COSV100710585; called by muse, mutect2
- APOB | c.11373C>T p.F3791= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV51935316; called by muse, mutect2, varscan2
- ASPM | c.5394C>T p.F1798= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs1292864938, COSV99659423; called by muse, mutect2, varscan2
- ATP10D | c.1275C>T p.I425= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs753814845, COSV56712202; called by muse, mutect2
- BDKRB1 | c.615G>A p.E205= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs768607326, COSV99387724; called by muse, mutect2, varscan2
- BIN1 | c.1716C>T p.N572= (on ENST00000316724 / NM_001320642.1; = p.N433= on NM_004305.4) | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99387425; called by muse, mutect2, varscan2
- C12orf50 | c.837G>A p.V279= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV53899461; called by muse, mutect2, varscan2
- CEP131 | c.1647C>T p.S549= (on ENST00000269392 / NM_001319228.2; = p.S546= on NM_014984.4) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99487780; called by muse, mutect2
- CHRNB3 | c.300C>T p.I100= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99250850; called by muse, mutect2, varscan2
- ELAVL4 | c.444G>A p.L148= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV63916394; called by muse, mutect2, varscan2
- EMILIN2 | c.2091G>A p.R697= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV99598085; called by muse, mutect2, varscan2
- ENPP1 | c.1783C>T p.L595= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100719365; called by muse, mutect2, varscan2
- ETV6 | c.297A>G p.K99= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV101122353; called by muse, mutect2, varscan2
- FADS3 | c.1005C>T p.F335= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs111249700, COSV53879798; called by muse, mutect2, varscan2
- FAT3 | c.12660C>T p.N4220= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs371295182, COSV99969007; called by muse, mutect2, varscan2
- FOSL2 | c.288C>T p.A96= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs747349464, COSV53105732; called by muse, mutect2, varscan2
- FOXN4 | c.1284C>T p.F428= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs748476694, COSV54493854; called by muse, mutect2, varscan2
- GLMP | c.60C>T p.L20= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1026181560, COSV55293431; called by muse, mutect2
- GNAZ | c.147C>T p.I49= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as rs1450405078, COSV99320378; called by muse, mutect2, varscan2
- GPR162 | c.627G>A p.R209= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99163685; called by muse, mutect2, varscan2
- GREM1 | c.174G>A p.R58= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100277776; called by muse, mutect2, varscan2
- GYS1 | c.1116C>T p.T372= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99620372; called by muse, mutect2, varscan2
- IP6K1 | c.528G>A p.E176= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100391212; called by muse, mutect2, varscan2
- JCAD | c.918A>T p.G306= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100948037; called by muse, mutect2, varscan2
- KCNJ3 | c.1158G>A p.V386= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV99715171; called by muse, mutect2, varscan2
- KIF21B | c.1047C>T p.P349= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100143504; called by muse, mutect2, varscan2
- KLHL1 | c.1920C>T p.V640= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs372198907; called by mutect2, varscan2
- KRT20 | c.1236C>T p.V412= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as rs1379016226, COSV51425672, COSV99391324; called by muse, mutect2, varscan2
- LAMA2 | c.6162G>A p.Q2054= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101369903; called by muse, mutect2, varscan2
- LAMP5 | c.459C>T p.F153= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99855414; called by muse, mutect2, varscan2
- LRP1B | c.8319C>T p.A2773= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV101251750; called by muse, mutect2, varscan2
- LRRIQ1 | c.3708C>T p.A1236= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV101279407, COSV67833467; called by muse, mutect2, varscan2
- LTBP2 | c.4572G>A p.K1524= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99999401, COSV99999599; called by muse, mutect2, varscan2
- MAP1A | c.726C>T p.P242= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100288010; called by muse, mutect2, varscan2
- MCTP1 | c.1686A>G p.E562= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56538465; called by muse, mutect2, varscan2
- MEOX1 | c.573C>T p.A191= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100233660, COSV100233846; called by muse, mutect2, varscan2
- NAV3 | c.1518C>T p.I506= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1378302814, COSV99886627; called by muse, mutect2, varscan2
- NEIL2 | c.118C>T p.L40= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1165064785, COSV99462074; called by muse, mutect2, varscan2
- OR2A5 | c.471G>A p.L157= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as COSV101278659; called by muse, mutect2, varscan2
- OR4B1 | c.549C>T p.F183= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs143803360, COSV58883417; called by muse, mutect2, varscan2
- OR4K17 | c.414G>A p.K138= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs1369814004, COSV100210473; called by muse, mutect2, varscan2
- OR4K17 | c.660G>A p.L220= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1215043581, COSV59648995; called by muse, mutect2, varscan2
- OR51B5 | c.555C>T p.L185= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs775172979, COSV56175390; called by muse, mutect2
- OR52K2 | c.528C>T p.I176= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as rs375297281; called by muse, mutect2, varscan2
- PCDHB2 | c.360G>A p.Q120= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99522765; called by muse, mutect2
- PDE1C | c.1767G>A p.G589= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as COSV58511669; called by muse, mutect2, varscan2
- PDIA4 | c.694C>T p.L232= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs368013782; called by muse, mutect2, varscan2
- PGD | c.828A>G p.V276= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99581097; called by muse, mutect2, varscan2
- PHYHIPL | c.1032C>T p.T344= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs758285455, COSV53244576, COSV53245758; called by muse, mutect2, varscan2
- PMFBP1 | c.2751G>A p.V917= (on ENST00000537465; = p.V912= on NM_031293.3) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs774423198, COSV52826765; called by muse, mutect2, varscan2
- RAI2 | c.198G>A p.Q66= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV58965265; called by muse, mutect2, varscan2
- RNF19A | c.2055G>A p.K685= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs762114396, COSV100347348; called by muse, mutect2, varscan2
- RTL6 | c.694C>T p.L232= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100373719; called by muse, mutect2, varscan2
- SDR9C7 | c.609G>A p.G203= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99524490; called by muse, mutect2, varscan2
- SDSL | c.987C>T p.V329= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100615152; called by muse, mutect2, varscan2
- SGSM3 | c.912G>A p.E304= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99960143; called by muse, mutect2, varscan2
- SLC2A7 | c.558C>T p.F186= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1474792500, COSV101280741; called by muse, mutect2, varscan2
- SOAT1 | c.288C>T p.T96= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs765958563, COSV100858868; called by muse, mutect2, varscan2
- SPR | c.601C>T p.L201= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99317985; called by muse, varscan2
- STEAP2 | c.963C>T p.L321= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99840209, COSV99840665; called by muse, mutect2, varscan2
- TM9SF4 | c.729C>T p.T243= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99453856; called by muse, mutect2, varscan2
- TOP2A | c.2913G>A p.K971= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV101396014; called by muse, mutect2, varscan2
- TRAV34 | c.13C>T p.L5= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- TRIM68 | c.1038C>T p.I346= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs955140989, COSV56167699; called by muse, mutect2, varscan2
- VCX2 | c.153G>A p.G51= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs755274372; called by muse, varscan2
- VPS13B | c.2991G>A p.E997= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100660785; called by muse, mutect2, varscan2
- WDR41 | c.154T>C p.L52= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99689048; called by muse, mutect2
- ZNF239 | c.1080G>A p.S360= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs527955576, COSV60018687; called by muse, mutect2, varscan2
- ZNF831 | c.726G>A p.S242= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV64040710; called by muse, mutect2, varscan2
- ZSCAN10 | c.2094C>T p.S698= (on ENST00000252463; = p.S753= on NM_032805.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1173672167, COSV99373802; called by muse, mutect2
- AC005863.1 | n.189C>T | RNA (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.333A>G | RNA (SNP) | VAF 3/38 reads (8%) | catalogued as COSV55596660, COSV99682895; called by muse, mutect2
- LEKR1 | c.*468G>A | 3'UTR (SNP) | VAF 19/61 reads (31%) | catalogued as rs767175894, COSV100738530; called by muse, mutect2, varscan2
- MLLT6 | c.819+234C>T | Intron (SNP) | VAF 7/50 reads (14%) | catalogued as rs1254772761; called by muse, mutect2, varscan2
- MSH5 | c.538-20C>T | Intron (SNP) | VAF 31/134 reads (23%) | catalogued as COSV100994654; called by muse, mutect2, varscan2
- SNORA71D | n.55G>A | RNA (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10360+2238G>A | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100592609; called by muse, mutect2, varscan2
